TCGA case TCGA-IB-8127 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b4443a0-087d-47e7-9e67-795eac6750c3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 59 years; Vital status: Alive.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 59.3 years (21,676 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 522 days (1.4 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 24; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 60 days; Days to treatment end: 194 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Pancreas, NOS. Age at diagnosis: 60.7 years (22,162 days); Days to diagnosis: 486 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 60.7 years (22,162 days); Days to diagnosis: 486 days (1.3 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 194 days; Disease response: Tumor Free.
- Day 486 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 486 days (1.3 years); Evidence of progression type: Convincing Image Source.
- Day 486 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pancreas, NOS; Days to recurrence: 486 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 522 days (1.4 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1971; Tobacco smoking quit year: 2011.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-8127-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.3; Intermediate dimension: 0.7; Shortest dimension: 0.2.
  Slide TCGA-IB-8127-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-IB-8127-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 71; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IB-8127-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-8127-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 522 days; disease-specific survival: no event (censored), 522 days; disease-free interval: event (new tumor event after initially disease-free), 486 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 486 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-8127-01A-11D-2392-01): tumor purity 0.35, ploidy 3.35, whole-genome doublings 1.
